Surgical pathology report (de-identified scan), TCGA case TCGA-DE-A4M8, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of North Carolina, specimen TCGA-DE-A4M8-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY

Case Number :

100-0-3

Diagnosis:

A: Lymph node, right superior thyroid, biopsy
- Benign parathyroid tissue
- No malignancy identified

CQCF:

Carcinoma, papillary, thyroid 8260/3

Path: carcinoma, papillary + follicular 8340/3

Site: thyroid C73.9

hw

10/2/12

B: Parathyroid, right superior, biopsy
- Scant parathyroid tissue
- No malignancy identified

C: Parathyroid, right, inferior, biopsy
- One lymph node, negative for carcinoma, present on original frozen section
only, tissue has been cut through on permanent sections.
- No parathyroid tissue present for evaluation

D: Thyroid, total thyroidectomy

Tumor type: papillary thyroid carcinoma, conventional and follicular subtypes

Tumor size: largest tumor focus measures 3.2 cm in the left lobe (D8)

Tumor growth pattern: infiltrative

Tumor focality & location: multifocal with extensive involvement of the right and left thyroid

Extent of invasion:

Capsular Invasion: not applicable

Lymphovascular invasion: not identified

Blood vascular invasion: not identified

Extra thyroidal extension invasion: not identified

Surgical margins: negative; <0.1 mm to the anterior margin, 0.1 mm to the posterior margin

Lymph nodes: 1 of 3 lymph nodes with involvement by metastatic papillary thyroid carcinoma (1/3) (D8)

[page 2 of 4]
Size of largest metastasis (greatest dimension): 0.2 mm

Extranodal extension: absent

Other significant findings:

- Multinodular hyperplasia
- Chronic lymphocytic thyroiditis

AJCC Pathologic Stage: pT2 pN1

NOTE: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Intraoperative Consult Diagnosis:

A frozen section was requested by

FSA1: Lymph node, right superior thyroid, biopsy

- Parathyroid tissue, no tumor or lymphoid tissue identified

FSB1: Parathyroid, right superior, removal

- Parathyroid tissue present. No tumor seen.

FSC1: Parathyroid, right inferior, biopsy

- Fragment of benign lymph node. No tumor seen. No parathyroid present.

Frozen Section Pathologist:, MD

Clinical History:

- year-old female with papillary thyroid cancer.

Gross Description:

Received are three appropriately labeled container, received fresh for frozen

[page 3 of 4]
section.

Container A is additionally labeled "right superior thyroid lymph node for frozen section." It consists of a 6 x 4 x 2 mm tan soft tissue fragment. The specimen is entirely submitted for frozen section and resubmitted in block FSA1,

Container B is additionally labeled "right superior parathyroid." It holds two red/tan soft tissue fragment in aggregate weighing less than 0.1 grams and measuring 0.3 x 0.1 x 0.2 cm. The specimen is submitted in block FSB1,

Container C is additionally labeled "right inferior parathyroid for frozen section." It consists of a less than 0.1 gram, 2 x 1 x 1 mm red/tan soft tissue fragment. The specimen is entirely submitted for frozen section and resubmitted in block FSC1,

Container D is additionally labeled "total thyroid".

Specimen fixation: Formalin

Type of specimen: Total thyroidectomy

Size and weight of specimen: 27 grams, right lobe (4.6 x 2.6 x 1.0 cm), left lobe (4.7 x 2.6 x 2.0 cm) and isthmus (2.0 x 0.7 x 0.5 cm).

Orientation: Inking: anterior/blue, posterior/black, isthmus/yellow

Tumor location: Right and left lobes

Focality: Multifocal

Dominant tumor: Left lobe (mid inferior pole)

Tumor description: Two of the nodules are firm, smooth gray/white and

[page 4 of 4]
well circumscribed (left and right lobes) with the largest having focal calcification. The third nodule is well-circumscribed pink/gray and semi gelatinous (left inferior pole), 0.1 cm from the dominant nodule.

Tumor size: Tumor in the right inferior pole (0.7 x 0.6 x 0.6 cm), dominant tumor in the left lobe (1.7 x 1.7 x 1.5 cm) and semi gelatinous nodule in the left inferior pole (1.4 x 1.2 x 1.1 cm).

Confinement / non-confinement: All tumors are confined.

Distance of tumor to capsule/inked surgical margins: All tumors grossly abut the capsule.

Appearance of thyroid gland away from tumor: Spongy red/brown with focal tan/gray discoloration in the mid superior right lobe.

Parathyroids: Not identified

Lymph nodes: N/A

Tissue submitted for special investigations: A portion of dominant nodule was given to tumor procurement foundation.

Digital photograph taken: No

Block Summary:

D1-D4 - Right inferior pole nodule, submitted entirely
D5 - Normal thyroid away from dominant nodule in the left lobe
D6-D11 - Dominant nodule from the left lobe submitted entirely
D12-D16- Semi-gelatinous nodule from the left lobe submitted entirely
D17-D20- Areas of gray/tan discoloration from the right mid superior lobe (approximately 50% of left lobe submitted and approximately 75% of right lobe submitted)

All nodules submitted entirely.

Discrepancy		
History Discrepancy		
Previous Discrepancy History		
Discrepancy Primary Tumor		
Calculation		
Review		
KMT		9/27/12

10/2/12

Source: NCI Genomic Data Commons file ba9d84f0-aaa9-4295-9165-f2ca29fa8af3 (TCGA-DE-A4M8.9DAE2966-D92F-4436-B3E3-5BC1923295BB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).